Surgical pathology report (de-identified scan), TCGA case TCGA-E1-5305, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-5305-01A (Primary Tumor).

[page 1 of 2]
Clinical History:

Brain tumor

Gross Examination:

A. "Brain tumor (AF1)", received fresh. A 3.3 x 2.4 x 1 cm aggregate of gray-tan gelatinous tissue is received. Representative portion is frozen as AF1, the remnant is submitted as A1. Additional sections are submitted as A2-3.

B. "Brain tumor (BF1)", received fresh. A 5 x 4.5 x 1.6 cm aggregate of tan-brown tissue is received. Representative portion is frozen as BF1, the remnant is submitted as B1. Additional sections are submitted as B2-4.

C. "Brain tumor", received fresh. A 6.5 x 3.5 x 2 cm aggregate of white-pink tissue is received. Representative sections are submitted as C1-5.

Intraoperative Consultation:

- A. "Brain tumor":AF1- astrocytoma grade deferred
B. "Brain tumor":BF1- astrocytoma, probable low grade

Microscopic Examination:

The specimen consist of a portion of brain tissue which is infiltrated by a glial neoplasm. In many areas the neoplastic cells are round and regular with punctate chromocenters with many gemistocyte forms. Focally it has evidence of oligodendroglial differentiation. Numerous microcysts with a mucinous material are identified. Other portions of the tumor, however, are composed of cells with increased nuclear and cytoplasmic pleomorphism and hyperchromatic elongated nuclei, these cells are more indicative of an astrocytic lineage. Focal areas of vascular endothelial proliferation are identified, and numerous mitotic figures are present. There is no evidence of unequivocal necrosis.

Immunohistochemical Findings:

An immunohistochemical stain for the KI-67 (proliferation related) antigen shows a labeling index of 5%.

Continued on next page...

Patient:

MRN:

Location:

[page 2 of 2]
DIAGNOSIS:

A. "BRAIN TUMOR":

ANAPLASTIC ASTROCYTOMA (WHO GRADE III)
/

B. "BRAIN TUMOR":

ANAPLASTIC ASTROCYTOMA (WHO GRADE III)
/

C. "BRAIN TUMOR":

ANAPLASTIC ASTROCYTOMA (WHO GRADE III)

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

Source: NCI Genomic Data Commons file 31c62bdb-c7fa-4540-9598-11e74dfb8700 (TCGA-E1-5305.7C854147-EDEB-47CA-9B46-444A18D12C43.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).